Gene-level copy-number profile of tumor specimen CDDP-ACM9-TTP1-A from CDDP_EAGLE case CDDP-ACM9, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 75 years.
Specimen CDDP-ACM9-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a72ae4a3-497a-411b-b85a-6f370bbd2828.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACM9-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,361 have no estimate.
https://portal.gdc.cancer.gov/files/9775c930-7cc5-47bf-aca6-fb092a5a337f

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 5; copy number 2: 158; copy number 3: 5,107; copy number 4: 27,054; copy number 5: 16,522; copy number 6: 5,178; copy number 7: 1,920; copy number 8: 1,187; copy number 9: 432; copy number 10: 472; copy number 11: 107; copy number 12: 59; copy number 13: 24; copy number 14: 8; copy number 15: 1; copy number 16: 6; copy number 22: 1; copy number 24: 6; copy number 28: 1; copy number 32: 14.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 1,131 genes in 79 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:144,085,628–144,373,659, 8 genes, copy number 14: IGKV1OR1-1, AC244015.1, AC244015.2, LINC02802, RNA5SP529, DRD5P2, AC245595.1, PPIAL4E.
- chr1:144,965,025–145,242,124, 7 genes, copy number 13–24: AC242498.1, FAM72D, LINC01145, RNU1-153P, AC241585.2, AC241585.1, PPIAL4D.
- chr1:145,289,900–145,859,836, 15 genes, copy number 9–10: NBPF20, PFN1P3, RNU1-154P, RNVU1-31, AC239860.2, AC239860.1, NBPF25P, GPR89A, PDZK1, CD160, RNF115, POLR3C, NUDT17, PIAS3, MIR6736.
- chr1:148,772,640–149,048,286, 5 genes, copy number 9–16 (within-gene range 7–18): SEC22B3P, AC245389.1, PDE4DIP, RN7SKP88, RNU2-38P.
- chr1:149,345,661–149,556,361, 4 genes, copy number 16: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr1:149,923,317–150,145,329, 6 genes, copy number 9–10: SF3B4, MTMR11, OTUD7B, AC244033.2, AC244033.1, VPS45.
- chr1:150,211,632–151,583,583, 78 genes, copy number 9–12 (broad region; genes not listed).
- chr1:151,755,541–151,805,419, 11 genes, copy number 9: AL589765.7, AL589765.3, MRPL9, OAZ3, AL589765.4, AL589765.2, AL589765.5, TDRKH, TDRKH-AS1, AL589765.6, LINGO4.
- chr1:153,533,603–154,870,281, 77 genes, copy number 9 (broad region; genes not listed).
- chr1:155,018,520–155,885,199, 53 genes, copy number 9–12 (within-gene range 8–12): DCST2, DCST1, DCST1-AS1, ADAM15, EFNA4, AL691442.1, EFNA3, Y_RNA, EFNA1, SLC50A1, DPM3, HMGN2P18, KRTCAP2, AL713999.2, TRIM46, MUC1, THBS3-AS1, MIR92B, THBS3, MTX1, AC234582.1, GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, ASH1L, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4, ASH1L-AS1, AL353807.4, DAP3P1, AL353807.1, AL353807.2, MSTO1, AL353807.3, AL353807.5, YY1AP1, DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11.
- chr1:156,192,063–156,248,117, 6 genes, copy number 9: AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6.
- chr2:88,383,494–88,452,693, 4 genes, copy number 9: RNU6-1168P, RNU6-1007P, RPL38P6, FOXI3.
- chr3:109,326,141–109,723,273, 6 genes, copy number 9 (within-gene range 6–9): DPPA4, AC124945.1, AC092905.1, H3P12, LINC01205, PPIAP15.
- chr3:141,936,707–142,149,544, 4 genes, copy number 9–10: AC112504.1, TFDP2, AC133435.1, RNU6-425P.
- chr5:10,171,030–10,249,897, 5 genes, copy number 9 (within-gene range 8–9): AC034229.5, AC034229.2, AC034229.3, AC034229.4, ATPSCKMT.
- chr7:73,005,541–73,111,140, 14 genes, copy number 32 (within-gene range 8–32): PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P.
- chr12:37,575,587–40,369,285, 34 genes, copy number 9–13: ZNF970P, AK6P2, CLUHP8, AC079460.1, AC079460.2, RNA5SP358, RNA5SP359, TUBB8P5, AC117372.1, NF1P12, Y_RNA, ALG10B, AC087897.1, AC087897.2, CPNE8, CPNE8-AS1, AC018448.2, AC018448.1, LINC02406, AC084373.1, KIF21A, AC121334.1, AC121334.2, ABCD2, AC121334.3, C12orf40, SLC2A13, AC121336.1, RPL30P13, LINC02555, LINC02471, LRRK2-DT, LRRK2, AC084290.1.
- chr12:42,069,935–42,590,355, 15 genes, copy number 9–10: AC023513.1, GXYLT1, YAF2, PPHLN1, AC020629.1, ZCRB1, MIR7851, SNORA74, AC079684.1, RNU6-249P, AC079601.2, Y_RNA, PRICKLE1, AC079601.1, AC079600.3.
- chr12:43,633,093–44,499,158, 11 genes, copy number 9: AC090525.3, EEF1A1P17, PUS7L, AC093012.1, IRAK4, TWF1, TMEM117, ZNF75BP, AC025030.2, AC025030.1, AC025253.1.
- chr12:45,173,064–45,445,438, 5 genes, copy number 9: PLEKHA8P1, AC009248.1, ANO6, AC009248.2, AC063924.1.
- chr12:47,237,734–49,357,546, 119 genes, copy number 9–11 (broad region; genes not listed).
- chr12:50,057,548–51,271,362, 44 genes, copy number 10–11: ASIC1, SMARCD1, GPD1, COX14, AC074032.1, CERS5, LIMA1, AC008147.2, AC008147.3, AC008147.1, MIR1293, RNU6-1093P, AC008147.4, LARP4, DIP2B, RNU6-769P, RNU6-238P, Y_RNA, AC013244.1, ATF1, AC013244.2, RN7SL519P, TMPRSS12, AC013244.3, METTL7A, AC008121.2, Y_RNA, AC008121.1, HIGD1C, AC008121.3, SLC11A2, RNU6-87P, RNU6-1273P, LETMD1, CSRNP2, TFCP2, RPL35AP29, PHBP19, Y_RNA, RNU6-199P, POU6F1, AC139768.1, DAZAP2, SMAGP.
- chr12:52,897,187–53,446,645, 29 genes, copy number 9–10: KRT8, KRT18, EIF4B, AC068888.2, AC068888.1, TNS2, MIR6757, SPRYD3, IGFBP6, SOAT2, VTI1BP3, RNU6-333P, HIGD1AP1, EIF4A1P4, CSAD, AC073573.1, ZNF740, ITGB7, RARG, MFSD5, ESPL1, PFDN5, AC073611.1, MYG1-AS1, MYG1, AAAS, SP7, AMHR2, PRR13.
- chr12:55,681,678–56,382,711, 64 genes, copy number 10 (broad region; genes not listed).
- chr12:56,521,820–56,688,408, 7 genes, copy number 9–10: RBMS2, RNU6-343P, BAZ2A, ATP5F1B, SNORD59A, PTGES3, RN7SL809P.
- chr12:57,249,609–57,808,071, 38 genes, copy number 9 (within-gene range 8–9): AC137834.1, R3HDM2, RNU6-879P, AC126614.1, INHBC, INHBE, AC022506.2, GLI1, ARHGAP9, MARS1, MIR6758, DDIT3, AC022506.1, MIR616, MBD6, DCTN2, KIF5A, PIP4K2C, DTX3, ARHGEF25, AC025165.1, AC025165.6, SLC26A10, B4GALNT1, RPL13AP23, OS9, AC025165.2, AGAP2, AGAP2-AS1, TSPAN31, CDK4, MIR6759, MARCHF9, CYP27B1, METTL1, EEF1AKMT3, AC025165.3, TSFM.
- chr12:64,404,392–64,609,459, 8 genes, copy number 9–10: XPOT, AC135279.2, AC135279.3, TBK1, AC136977.1, AC078962.2, SNORD83, AC078962.4.
- chr12:68,746,125–68,850,686, 6 genes, copy number 9 (within-gene range 8–9): SLC35E3, AC025423.3, MDM2, AC025423.1, AC025423.4, AC025423.2.
- chr12:75,275,979–75,390,928, 4 genes, copy number 9 (within-gene range 7–9): CAPS2, AC092552.1, AC121761.2, GLIPR1L1.
- chr12:76,137,425–76,757,914, 13 genes, copy number 9: AC233290.1, RNU6-1271P, LNCOG, RN7SKP172, BBS10, OSBPL8, AC107032.2, AC107032.3, RPL7AP9, YWHAQP7, AC107032.1, RPL7P43, AC093014.1.
- chr17:19,063,346–19,214,045, 19 genes, copy number 13: SNORD3B-2, AC007952.3, KYNUP2, AC007952.7, AC007952.2, AC007952.4, SNORD3D, SNORD3D, GRAPL, AC007952.6, AC007952.9, AC007952.1, AC007952.5, AC007952.8, KYNUP1, SNORD3A, SNORD3C, AC106017.1, KYNUP3.
- chr19:27,638,483–28,396,428, 18 genes, copy number 10: ERVK-28, AC112702.1, LINC00662, AC006504.1, AC006504.5, AC006504.7, AC006504.3, SLC25A1P5, AC006504.2, AC006504.4, AC005357.2, AC006504.6, AC005758.1, AC005357.1, AC010511.1, AC020905.1, AC005580.1, AC093074.1.
- chr19:29,811,991–30,038,181, 9 genes, copy number 9–10: CCNE1, AC008798.1, AC008507.3, PPIAP58, URI1, RPL9P32, AC008507.2, TAF9P3, AC008507.1.
- chr19:32,978,592–33,208,864, 7 genes, copy number 10 (within-gene range 7–10): RHPN2, AC008521.1, AC008521.2, GPATCH1, WDR88, LRP3, AC008738.1.
- chr19:34,254,552–34,512,304, 10 genes, copy number 10: GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1, UBA2, WTIP.
- chr19:35,825,372–39,182,816, 156 genes, copy number 9–12 (broad region; genes not listed).
- chr19:39,296,407–39,520,686, 16 genes, copy number 9–12: IFNL1, LRFN1, GMFG, AC011445.1, SAMD4B, RN7SL566P, PAF1, MED29, ZFP36, MIR4530, PLEKHG2, RPS16, SUPT5H, TIMM50, DLL3, SELENOV.
- chr19:39,943,239–41,444,765, 85 genes, copy number 9–12 (broad region; genes not listed).
- chr19:44,725,984–45,526,983, 45 genes, copy number 10: AC243964.2, BCL3, MIR8085, SNORA70, AC092066.1, CBLC, BCAM, NECTIN2, AC011481.2, TOMM40, APOE, AC011481.3, APOC1, APOC1P1, APOC4, APOC4-APOC2, APOC2, AC011481.1, CLPTM1, RELB, CLASRP, RNU6-611P, ZNF296, GEMIN7-AS1, GEMIN7, MARK4, PPP1R37, EIF5AP3, AC005757.1, NKPD1, TRAPPC6A, BLOC1S3, EXOC3L2, CKM, RPS16P9, KLC3, ERCC2, PPP1R13L, POLR1G, ERCC1, MIR6088, FOSB, RTN2, PPM1N, VASP.
- chr19:45,606,994–45,683,722, 7 genes, copy number 10: EML2, MIR330, EML2-AS1, RN7SL836P, GIPR, MIR642A, MIR642B.

Autosomal genes at a single copy (total copy number 1): 5. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
